Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3867, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3867-01A (Primary Tumor).

Diagnosis/ diagnoses

Resected section of colon (sigma) with an ulcerated colon carcinoma histologically characterized as a poorly differentiated colorectal adenocarcinoma, extending within 0.5 cm of one resection margin, almost completely encircling the intestinal wall and measuring a max of 3 cm in diameter. Invasive tumor spread within all intestinal wall layers as far as the periproctical fatty tissue layer. Lymphangial branches in the tumor margin area.

Oral and aboral resection margins are tumor-free.

Four out of 24 mesocolic lymph nodes with extensive metastases of the colon carcinoma, partly transgressing the lymph node capsules. The remaining lymph nodes have uncharacteristically reactive lesions.

Therefore the tumor stage is: pT3, pN2 (4/24) L1, V0; G3

Source: NCI Genomic Data Commons file b5b07d7e-0058-471d-a729-f6390a2d4813 (TCGA-AA-3867.A2D8E110-7F5C-4B41-9084-405564F4BC9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).